Somatic mutation profile of tumor specimen MP2PRT-PARWFC-TMP1-A (aliquot MP2PRT-PARWFC-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARWFC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,145 days).
Specimen MP2PRT-PARWFC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca091269-8e49-4c9a-982b-fabadf187145.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWFC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWFC-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343b4521-0596-4410-8388-fad0e5c31101

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC141 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs372583176; called by muse, mutect2, varscan2
- HIC2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 23/817 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); catalogued as COSV68042718; called by muse, mutect2
- IGKJ5 | c.1_2insGCG p.*1_I2insA | In Frame Ins (INS) | VAF 32/236 reads (14%) | called by mutect2, pindel, varscan2
- PYGO1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 102/459 reads (22%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CT47B1 | c.234C>T p.G78= | Silent (SNP) | VAF 40/1260 reads (3%) | catalogued as COSV100988871; called by muse, mutect2
- GSG1L | c.225C>A p.T75= | Silent (SNP) | VAF 136/877 reads (16%) | called by mutect2, varscan2
- KYNU | c.1179G>A p.P393= | Silent (SNP) | VAF 56/365 reads (15%) | catalogued as rs145299669, COSV51581609; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899617 ins C | 3'Flank (INS) | VAF 71/488 reads (15%) | called by mutect2, pindel, varscan2
